CCDI case PBCBKR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8f5d17d9-fa7b-4be1-8202-4df357954fb6

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (576 days).

Biospecimens (3 samples)
- Sample 0DOV8F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOV8V: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOV95: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
